Somatic mutation profile of tumor specimen TCGA-DD-A73D-01A (aliquot TCGA-DD-A73D-01A-12D-A32G-10) from TCGA case TCGA-DD-A73D, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G1; Age at diagnosis: 68.3 years (24,941 days).
Specimen TCGA-DD-A73D-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c1d92aba-b499-45d8-bdef-b5c504fe45e6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-A73D-10A (Blood Derived Normal), aliquot TCGA-DD-A73D-10A-01D-A32G-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/04c1e428-8f8a-4d1e-ac11-e92b1bbf1c3e

The open-access MAF lists 75 somatic variants for this specimen: 59 protein-altering or splice-affecting, 16 silent.
By variant classification: Missense Mutation 50, Silent 16, Frame Shift Del 5, Splice Site 3, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.95A>G p.D32G | Missense Mutation (SNP) | VAF 76/136 reads (56%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs121913396, COSV62688001, COSV62688037, COSV62688249; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- FH | c.1008G>A p.M336I | Missense Mutation (SNP) | VAF 104/207 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV63817629; called by muse, mutect2
- FH | c.1006A>C p.M336L | Missense Mutation (SNP) | VAF 106/210 reads (50%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen benign (0.149); catalogued as COSV63818119; called by muse, mutect2
- ANGPTL6 | c.1126C>T p.R376W | Missense Mutation (SNP) | VAF 36/84 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1255570940, COSV53462100; called by muse, mutect2, varscan2
- BAZ2B | c.1350C>G p.S450R | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.299); catalogued as COSV58599869; called by muse, mutect2, varscan2
- CALR | c.1245C>G p.D415E | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.007); catalogued as rs148604761, COSV100330900, COSV57124074; called by muse, mutect2, varscan2
- CDC20B | c.1069G>T p.A357S | Missense Mutation (SNP) | VAF 5/62 reads (8%) | SIFT tolerated (0.67); PolyPhen benign (0.306); catalogued as COSV57051945; called by muse, mutect2
- CDC73 | c.587C>G p.T196S | Missense Mutation (SNP) | VAF 40/212 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); catalogued as COSV66466691; called by muse, mutect2, varscan2
- CELF5 | c.373G>A p.D125N | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.09); catalogued as COSV53011392; called by muse, mutect2, varscan2
- COMMD3 | c.431T>G p.M144R | Missense Mutation (SNP) | VAF 56/291 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.085); catalogued as COSV64958996; called by muse, mutect2, varscan2
- COX5A | c.120C>G p.C40W | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.76); catalogued as COSV59279344; called by muse, mutect2, varscan2
- DPP10 | c.859C>G p.Q287E | Missense Mutation (SNP) | VAF 59/101 reads (58%) | SIFT tolerated (0.52); PolyPhen benign (0.013); catalogued as COSV59683381, COSV59727528; called by muse, mutect2, varscan2
- F10 | c.1206G>A p.M402I | Missense Mutation (SNP) | VAF 33/66 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65021559; called by muse, mutect2, varscan2
- FAAH | c.196-2A>G p.X66_splice | Splice Site (SNP) | VAF 24/65 reads (37%) | catalogued as COSV54543932; called by muse, mutect2, varscan2
- FAM24A | c.212C>G p.T71S | Missense Mutation (SNP) | VAF 42/91 reads (46%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV100925069, COSV64405905; called by muse, mutect2, varscan2
- GALNT15 | c.427G>A p.V143M | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.11); PolyPhen benign (0.054); catalogued as COSV60216812; called by muse, mutect2, varscan2
- GLI3 | c.1768G>T p.A590S | Missense Mutation (SNP) | VAF 110/166 reads (66%) | SIFT deleterious (0); PolyPhen benign (0.199); catalogued as COSV67887965; called by muse, mutect2, varscan2
- GLRA4 | c.758G>A p.R253Q | Missense Mutation (SNP) | VAF 91/213 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779430732, COSV101009661, COSV65455768; called by muse, mutect2, varscan2
- GNPTG | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.269); catalogued as rs748204437, COSV50190001; called by muse, mutect2, varscan2
- GRM8 | c.2554C>T p.R852C | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as rs139289550; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- H1-2 | c.478A>G p.K160E | Missense Mutation (SNP) | VAF 238/304 reads (78%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV59190618; called by muse, varscan2
- IER3 | c.7C>T p.H3Y | Missense Mutation (SNP) | VAF 97/127 reads (76%) | SIFT tolerated (0.36); PolyPhen benign (0.442); catalogued as COSV52543815; called by muse, mutect2, varscan2
- IL10RA | c.439A>T p.R147W | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV57140412; called by muse, mutect2, varscan2
- IRF9 | c.172T>G p.F58V | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.156); catalogued as COSV100138119; called by muse, mutect2, varscan2
- IRF9 | c.173T>C p.F58S | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); catalogued as COSV100138120; called by muse, mutect2, varscan2
- ITGAL | c.1733T>C p.I578T | Missense Mutation (SNP) | VAF 44/95 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as COSV63322016; called by muse, mutect2, varscan2
- KCNK9 | c.356C>A p.P119Q | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57281005; called by muse, mutect2, varscan2
- KIT | c.2803-1G>T p.X935_splice | Splice Site (SNP) | VAF 29/63 reads (46%) | catalogued as COSV55398704; called by muse, mutect2, varscan2
- LDLRAD1 | c.310C>T p.H104Y | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as COSV62810036; called by muse, mutect2, varscan2
- LHX9 | c.806G>A p.R269H | Missense Mutation (SNP) | VAF 108/203 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61327762; called by muse, mutect2, varscan2
- LMTK3 | c.1567G>T p.V523L | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.86); catalogued as COSV54311923; called by muse, mutect2, varscan2
- LRRC43 | c.1865C>T p.P622L | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV57336224; called by muse, mutect2, varscan2
- MAPKAPK3 | c.220-1G>A p.X74_splice | Splice Site (SNP) | VAF 33/74 reads (45%) | catalogued as COSV63597315; called by muse, mutect2, varscan2
- MARK1 | c.731G>T p.G244V | Missense Mutation (SNP) | VAF 35/155 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV65067296; called by muse, mutect2, varscan2
- OR6Y1 | c.598G>T p.A200S | Missense Mutation (SNP) | VAF 61/120 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV56929260; called by muse, mutect2, varscan2
- OR9G4 | c.630C>A p.S210R | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.444); catalogued as COSV57248424; called by muse, mutect2, varscan2
- OSBPL10 | c.1343G>T p.G448V | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV67338806, COSV67339445; called by muse, mutect2, varscan2
- PCDHGB2 | c.2215G>T p.V739F | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.83); PolyPhen benign (0.062); catalogued as COSV53938667; called by muse, mutect2, varscan2
- PRDM5 | c.887T>C p.I296T | Missense Mutation (SNP) | VAF 61/146 reads (42%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as COSV53359801; called by muse, mutect2, varscan2
- PRX | c.532C>A p.P178T | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV52529608; called by muse, mutect2, varscan2
- RLIM | c.1138A>T p.S380C | Missense Mutation (SNP) | VAF 55/102 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60326239; called by muse, mutect2, varscan2
- RNF39 | c.146C>T p.A49V | Missense Mutation (SNP) | VAF 8/146 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs767070867, COSV54993216; called by muse, mutect2
- SEMA6C | c.2567G>A p.G856D | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.01); catalogued as COSV59002561; called by muse, mutect2, varscan2
- SLC25A34 | c.539G>T p.G180V | Missense Mutation (SNP) | VAF 32/68 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV53816866; called by muse, varscan2
- SLC38A10 | c.1738G>A p.V580I | Missense Mutation (SNP) | VAF 25/175 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV55845042; called by muse, mutect2, varscan2
- SOX30 | c.1731T>A p.S577R | Missense Mutation (SNP) | VAF 37/84 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.462); catalogued as COSV53937264; called by muse, mutect2, varscan2
- SP3 | c.670A>G p.I224V | Missense Mutation (SNP) | VAF 65/100 reads (65%) | SIFT tolerated (0.24); PolyPhen benign (0.015); catalogued as rs759683077, COSV59467449; called by muse, mutect2, varscan2
- SPTAN1 | c.842A>G p.D281G | Missense Mutation (SNP) | VAF 30/62 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV63986859; called by muse, mutect2, varscan2
- STAT1 | c.331G>A p.E111K | Missense Mutation (SNP) | VAF 73/125 reads (58%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.876); catalogued as COSV63115910; called by muse, mutect2, varscan2
- TP53BP2 | c.57T>G p.N19K | Missense Mutation (SNP) | VAF 64/132 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as COSV59068115; called by muse, mutect2, varscan2
- TRIM29 | c.398C>T p.S133L | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as rs1027431435, COSV59279297; called by muse, mutect2, varscan2
- USP19 | c.1748G>T p.G583V | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60045805; called by muse, mutect2, varscan2
- ZC2HC1A | c.218C>A p.P73Q | Missense Mutation (SNP) | VAF 81/265 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV55668494; called by muse, mutect2, varscan2
- ADGRE5 | c.1709del p.L570Rfs*61 (on ENST00000242786 / NM_078481.4; = p.L477Rfs*61 on NM_001784.5) | Frame Shift Del (DEL) | VAF 17/42 reads (40%) | called by mutect2, pindel, varscan2
- ARID2 | c.683del p.K228Rfs*64 | Frame Shift Del (DEL) | VAF 156/427 reads (37%) | called by mutect2, pindel, varscan2
- CAND1 | c.3008del p.L1003Rfs*2 | Frame Shift Del (DEL) | VAF 38/91 reads (42%) | called by mutect2, pindel, varscan2
- FRMD6 | c.1235_1259del p.Y412Cfs*2 (on ENST00000344768 / NM_001267046.2; = p.Y404Cfs*2 on NM_152330.4) | Frame Shift Del (DEL) | VAF 15/62 reads (24%) | called by mutect2, pindel, varscan2
- MAGEB6B | c.313G>T p.E105* | Nonsense Mutation (SNP) | VAF 22/48 reads (46%) | called by muse, mutect2, varscan2
- ZNF227 | c.511_514del p.F171Gfs*12 | Frame Shift Del (DEL) | VAF 43/119 reads (36%) | called by mutect2, pindel, varscan2
- C3 | c.2601C>T p.L867= | Silent (SNP) | VAF 21/45 reads (47%) | catalogued as COSV55572377; called by muse, mutect2, varscan2
- CHRM4 | c.570G>C p.L190= | Silent (SNP) | VAF 36/75 reads (48%) | catalogued as COSV63126455; called by muse, mutect2, varscan2
- CNR1 | c.879G>A p.A293= | Silent (SNP) | VAF 19/43 reads (44%) | catalogued as rs35057475; called by muse, mutect2, varscan2
- CPEB2 | c.2907C>T p.G969= | Silent (SNP) | VAF 40/113 reads (35%) | catalogued as rs1020027443, COSV52591455; called by muse, mutect2, varscan2
- CYP2F1 | c.228G>A p.V76= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as COSV58527346; called by muse, mutect2, varscan2
- DCHS1 | c.1743T>C p.T581= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as COSV55034801; called by mutect2, varscan2
- EML3 | c.1527G>A p.Q509= | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as COSV53871842; called by muse, mutect2, varscan2
- FCGBP | c.7974G>A p.K2658= | Silent (SNP) | VAF 74/356 reads (21%) | called by muse, mutect2
- OR8A1 | c.789A>C p.T263= | Silent (SNP) | VAF 37/82 reads (45%) | catalogued as COSV52508492; called by muse, mutect2, varscan2
- PSMD1 | c.396C>T p.G132= | Silent (SNP) | VAF 14/107 reads (13%) | catalogued as COSV58078384; called by muse, mutect2, varscan2
- SIGLEC8 | c.552G>T p.G184= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as COSV58473527; called by muse, mutect2, varscan2
- SLC12A5 | c.276C>A p.T92= (on ENST00000454036 / NM_001134771.2; = p.T69= on NM_020708.5) | Silent (SNP) | VAF 28/67 reads (42%) | catalogued as COSV54790276, COSV54792893; called by muse, mutect2, varscan2
- TEX9 | c.561C>T p.D187= | Silent (SNP) | VAF 67/140 reads (48%) | catalogued as COSV61878016; called by muse, mutect2, varscan2
- TTN | c.29883T>C p.A9961= (on ENST00000591111; = p.A9034= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 47/79 reads (59%) | catalogued as COSV60023678; called by muse, mutect2, varscan2
- VEPH1 | c.1089T>G p.L363= | Silent (SNP) | VAF 43/102 reads (42%) | catalogued as COSV62878489; called by muse, mutect2, varscan2
- WASHC5 | c.3222A>T p.P1074= | Silent (SNP) | VAF 30/84 reads (36%) | catalogued as COSV59196045; called by muse, mutect2, varscan2
